Gene-level copy-number profile of tumor specimen C3N-06997-01 (profiled together with C3N-06997-02) from CPTAC case C3N-06997, project CPTAC-3 (Skin — Nevi and Melanomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage IIIC; Age at diagnosis: 71.7 years (26,172 days).
Specimen C3N-06997-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Trunk; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 22225534-59cf-41a4-8e84-0a5282e37358.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-06997-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,711 have no estimate.
https://portal.gdc.cancer.gov/files/8f86cdc4-1c0b-43b6-bd95-2c16311e334d

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 476; copy number 1: 10,753; copy number 2: 46,675; copy number 3: 605; copy number 4: 9; copy number 5: 310; copy number 12: 18; copy number 13: 7; copy number 14: 20; copy number 15: 39.

Homozygous deletions (total copy number 0; autosomes only): 271 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr9:8,314,246–13,836,571, 35 genes (within-gene range 0–1): PTPRD, AL583805.2, AL583805.1, RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P, AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1, AL583785.1, LINC01235.
- chr9:14,081,843–14,910,995, 14 genes: NFIB, AL441963.1, AL136366.1, AL137017.1, AL159169.1, AL159169.3, AL159169.2, CDCA4P1, ZDHHC21, CER1, FREM1, AL512643.2, AL512643.1, RNU6-1260P.
- chr9:15,553,043–16,061,663, 3 genes: CCDC171, HMGN2P16, RNU6-14P.
- chr9:17,447,145–17,797,124, 3 genes (within-gene range 0–1): SAMM50P1, SH3GL2, PABPC1P11.
- chr9:20,331,446–20,332,277, 1 gene: AL512635.1.
- chr9:20,411,148–20,418,427, 2 genes (within-gene range 0–1): MIR4473, RNU4-26P.
- chr9:20,658,309–23,438,700, 64 genes (within-gene range 0–1) (broad region; genes not listed).
- chr9:24,542,952–27,944,497, 34 genes: IZUMO3, AL353811.1, RMRPP5, RN7SKP120, TUSC1, LINC01241, FAM71BP1, AL353753.1, AL442639.1, AL451137.2, AL451137.1, AL356133.1, CAAP1, H3P31, RN7SL100P, PLAA, IFT74, IFT74-AS1, LRRC19, AL355432.1, TEK, RNA5SP280, AL355433.1, LINC00032, EQTN, MOB3B, AL163192.1, AL451123.2, IFNK, AL451123.1, C9orf72, CTAGE12P, AL360014.1, AL353746.1.
- chr9:39,631,046–39,810,097, 7 genes: FKBP4P2, SDR42E1P1, ATP5F1AP8, RAB28P1, RBPJP5, GLIDR, BX664615.1.
- chr9:41,644,438–62,435,199, 79 genes (broad region; genes not listed).
- chr9:64,369,394–64,889,063, 18 genes: ANKRD20A4P, RNU6-1193P, SNX18P9, CR769776.2, CYP4F25P, CR769776.1, CNN2P3, GXYLT1P6, AL773524.1, AQP7P2, AL445665.1, BMS1P11, AL359955.2, IGKV1OR-2, BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.
- chr10:48,009,873–48,119,455, 4 genes: AGAP12P, RNA5SP315, BMS1P7, PTPN20CP.
- chr16:90,102,271–90,222,851, 6 genes: FAM157C, AC133919.1, AC133919.2, RNU6-355P, LINC02193, CICP25.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 394 genes in 18 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr13:19,674,752–19,865,048, 6 genes, copy number 12 (within-gene range 1–12): PSPC1, RN7SL166P, ST6GALNAC4P1, ZMYM5, AL355001.1, AL355001.2.
- chr13:21,224,521–21,295,003, 3 genes, copy number 12: LINC01046, ESRRAP2, AL158032.2.
- chr13:43,213,518–43,786,908, 1 gene, copy number 15 (within-gene range 2–15): ENOX1.
- chr13:43,458,465–44,030,461, 12 genes, copy number 15: ENOX1-AS2, ENOX1-AS1, AL161714.1, AL162713.2, AL162713.1, CCDC122, AL512506.1, LACC1, AL512506.3, AL512506.2, NRAD1, DGKZP1.
- chr13:57,631,744–58,752,233, 9 genes, copy number 12: PCDH17, AL445288.1, RNA5SP30, LINC02338, LINC00374, AL161423.1, RNY4P29, CTAGE16P, DNAJA1P1.
- chr13:66,302,834–67,230,445, 1 gene, copy number 14 (within-gene range 2–14): PCDH9.
- chr13:66,630,715–67,156,624, 5 genes, copy number 14: RNU7-87P, PCDH9-AS2, PCDH9-AS3, PCDH9-AS4, AL160254.1.
- chr13:68,634,190–68,986,064, 6 genes, copy number 13: RPS3AP52, RPL12P34, RN7SL761P, LINC00550, LINC02342, ZDHHC20P4.
- chr13:74,231,457–75,482,169, 15 genes, copy number 14–15: LINC00402, AL353660.1, RNY1P5, RPL21P108, AL355390.1, LINC00381, AL355390.2, LINC00347, RIOK3P1, RNU6-38P, SSR1P2, CTAGE11P, LINC01078, TBC1D4, AL139230.1.
- chr13:77,026,767–77,129,717, 1 gene, copy number 15 (within-gene range 2–15): MYCBP2-AS1.
- chr13:77,044,657–77,327,094, 1 gene, copy number 15 (within-gene range 2–15): MYCBP2.
- chr13:77,535,674–77,844,145, 8 genes, copy number 15: SCEL, AL137140.1, SCEL-AS1, RNY3P7, SPTLC1P5, SLAIN1, MIR3665, EDNRB-AS1.
- chr13:83,298,071–83,298,167, 1 gene, copy number 13: RNU6-67P.
- chr13:91,023,732–91,354,579, 11 genes, copy number 15: BRK1P2, LINC00380, LINC00379, PPIAP23, MIR17HG, MIR17, MIR18A, MIR19A, MIR20A, MIR19B1, MIR92A1.
- chr13:95,677,139–95,794,988, 1 gene, copy number 15 (within-gene range 2–15): DNAJC3.
- chr13:95,744,726–96,053,482, 3 genes, copy number 15: AL138955.1, UGGT2, HMGN1P24.
- chr20:50,510,321–59,460,837, 157 genes, copy number 5 (broad region; genes not listed).
- chr20:60,055,853–64,327,972, 153 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,409. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
